Somatic mutation profile of tumor specimen TCGA-44-7667-01A (aliquot TCGA-44-7667-01A-31D-2063-08) from TCGA case TCGA-44-7667, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 49.5 years (18,062 days).
Specimen TCGA-44-7667-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 964b8ceb-a3d4-4896-ab7a-7f11cecf2a20.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-7667-10A (Blood Derived Normal), aliquot TCGA-44-7667-10A-01D-2063-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67a6c7e0-baab-44e0-8f2f-c832a78b2add

The open-access MAF lists 500 somatic variants for this specimen: 376 protein-altering or splice-affecting, 109 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 320, Silent 109, Nonsense Mutation 28, Splice Site 10, Frame Shift Del 8, RNA 6, Intron 5, Frame Shift Ins 5, In Frame Del 3, 5'UTR 2, Splice Region 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD12 | c.506C>G p.P169R | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV59286360; called by muse, mutect2
- AC004922.1 | c.1705G>A p.V569I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as rs776539765, COSV53163583; called by mutect2, varscan2
- ACACB | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 53/172 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV100623094, COSV58132067; called by muse, mutect2, varscan2
- ACY3 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54829014; called by muse, mutect2, varscan2
- ADAMTS20 | c.4606A>T p.M1536L | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV101239700, COSV67132994; called by muse, mutect2, varscan2
- ADGRG4 | c.9050G>T p.R3017L | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV54958141, COSV54961691; called by muse, mutect2, varscan2
- ADH1A | c.450C>A p.Y150* | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | catalogued as COSV52925193; called by muse, mutect2, varscan2
- ADSS1 | c.835G>A p.G279S | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs574062486, COSV100272349; called by muse, mutect2, varscan2
- ADSS1 | c.836G>T p.G279V | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100272354; called by muse, mutect2, varscan2
- AGMO | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61108337; called by muse, mutect2, varscan2
- AGO4 | c.1387A>T p.T463S | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as COSV100942739, COSV64617373; called by muse, mutect2, varscan2
- AGPAT1 | c.848G>T p.G283V | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV61247854; called by muse, mutect2, varscan2
- AGXT2 | c.1537G>T p.A513S | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.555); catalogued as COSV99183789; called by muse, mutect2
- AHNAK2 | c.5382G>C p.E1794D | Missense Mutation (SNP) | VAF 91/241 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV60917779; called by muse, mutect2, varscan2
- AMER3 | c.1037G>T p.G346V | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.342); catalogued as COSV58467362; called by muse, mutect2, varscan2
- AMIGO2 | c.1499C>G p.T500R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.055); catalogued as COSV56974439, COSV56974790, COSV99873712; called by mutect2, varscan2
- ANAPC1 | c.1702G>A p.D568N | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.111); catalogued as COSV61976671; called by muse, mutect2
- ANK2 | c.6401C>A p.T2134N | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52165636; called by muse, mutect2, varscan2
- ANKRD33 | c.-5-5G>T | Splice Region (SNP) | VAF 13/57 reads (23%) | catalogued as COSV100001418; called by muse, mutect2, varscan2
- ANKRD34A | c.920G>T p.S307I | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV60161153; called by muse, mutect2, varscan2
- ANO7 | c.1592G>A p.R531K (on ENST00000274979; = p.R477K on NM_001370694.2) | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as rs1172655910, COSV51472899; called by muse, mutect2
- AP002512.3 | c.545C>G p.P182R | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1402001433, COSV54407044; called by muse, mutect2, varscan2
- ARHGAP32 | c.1150G>T p.E384* (on ENST00000310343 / NM_001378025.1; = p.E35* on NM_014715.4) | Nonsense Mutation (SNP) | VAF 34/81 reads (42%) | catalogued as COSV59849364; called by muse, mutect2, varscan2
- ARHGEF17 | c.3717G>T p.E1239D | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55233311; called by muse, mutect2, varscan2
- ARID1A | c.3607A>T p.N1203Y | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61379321; called by muse, mutect2, varscan2
- ARMC4 | c.1480G>T p.G494* | Nonsense Mutation (SNP) | VAF 23/96 reads (24%) | catalogued as COSV59465124; called by muse, mutect2, varscan2
- ARV1 | c.595T>C p.W199R | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59617960; called by muse, mutect2, varscan2
- ASAP1 | c.2578G>T p.D860Y | Missense Mutation (SNP) | VAF 13/224 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.925); catalogued as rs765339752, COSV63049557; called by muse, mutect2
- ATP12A | c.2727C>A p.Y909* | Nonsense Mutation (SNP) | VAF 33/73 reads (45%) | catalogued as rs746587343, COSV54517754; called by muse, mutect2, varscan2
- ATP13A2 | c.221G>T p.R74L | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV58701156, COSV58704128; called by muse, mutect2, varscan2
- ATP8A2 | c.670G>T p.D224Y | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.461); catalogued as COSV54956201; called by muse, mutect2, varscan2
- ATP8A2 | c.2159G>T p.R720L | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV54956209; called by muse, mutect2, varscan2
- ATR | c.2752A>G p.K918E | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs977085317, COSV63387306; called by muse, mutect2, varscan2
- AXDND1 | c.1466T>C p.I489T | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.039); catalogued as rs780651712, COSV62643571; called by muse, mutect2, varscan2
- BABAM1 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs376352234; called by mutect2, varscan2
- BCL2L2-PABPN1 | c.1073C>G p.A358G (on ENST00000678502; = p.A326G on NM_001199864.2) | Missense Mutation (SNP) | VAF 67/146 reads (46%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.123); catalogued as COSV53729752; called by muse, mutect2, varscan2
- BDP1 | c.2387A>G p.N796S | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.189); catalogued as rs752122551, COSV62431930; called by muse, mutect2, varscan2
- BMPR2 | c.181T>A p.S61T | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV65810065; called by muse, mutect2, varscan2
- BPIFB1 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.49); catalogued as COSV53606906; called by muse, mutect2, varscan2
- BRPF3 | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV60207861; called by muse, mutect2, varscan2
- C1QB | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.194); catalogued as COSV59245511; called by muse, mutect2
- CABYR | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 117/167 reads (70%) | SIFT tolerated (0.12); PolyPhen benign (0.184); catalogued as rs1445745353, COSV59111275; called by muse, mutect2, varscan2
- CACNA1A | c.3102A>G p.K1034= | Splice Region (SNP) | VAF 16/24 reads (67%) | catalogued as COSV64200165; called by muse, mutect2, varscan2
- CACNA1I | c.5693G>T p.R1898L | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV60810557; called by muse, mutect2, varscan2
- CACNG7 | c.320G>T p.S107I | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV55814884; called by muse, mutect2, varscan2
- CAPS2 | c.1495G>T p.G499C | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60826114; called by muse, mutect2, varscan2
- CCDC170 | c.1085G>C p.R362T | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as COSV53341703; called by muse, mutect2, varscan2
- CCDC22 | c.91A>T p.T31S | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.36); PolyPhen benign (0.034); catalogued as COSV59904938; called by muse, varscan2
- CCDC63 | c.1169C>T p.T390M | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs747278168, COSV57528912; called by muse, mutect2, varscan2
- CDH10 | c.2195C>A p.S732* | Nonsense Mutation (SNP) | VAF 41/139 reads (29%) | catalogued as COSV52583761, COSV52584608; called by muse, mutect2, varscan2
- CDH12 | c.1968C>A p.N656K | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101202499, COSV66411353; called by muse, mutect2, varscan2
- CENPF | c.2535G>T p.M845I | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as COSV65275586; called by muse, mutect2
- CEP120 | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as COSV60266103; called by muse, mutect2, varscan2
- CFAP44 | c.2375A>T p.K792I | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.365); catalogued as COSV55612188; called by muse, mutect2, varscan2
- CGB1 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as rs766888572, COSV56820127, COSV56820492; called by muse, mutect2, varscan2
- CHL1 | c.479C>G p.P160R | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56595424; called by muse, mutect2, varscan2
- CLCA4 | c.1195C>A p.L399I | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV55368677; called by muse, mutect2, varscan2
- CLCN1 | c.1780G>T p.G594C | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV58370643; called by muse, mutect2, varscan2
- CLIC2 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs782037891, COSV58935875, COSV58936587; called by muse, mutect2
- CNOT1 | c.5798A>T p.Y1933F | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV55312928, COSV55317748; called by muse, mutect2, varscan2
- CNTN1 | c.2162G>C p.R721T | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.811); catalogued as COSV61636104, COSV61640703; called by muse, mutect2, varscan2
- COL11A1 | c.5111C>A p.A1704D | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as COSV62185638; called by muse, mutect2, varscan2
- COL12A1 | c.2023G>T p.V675F | Missense Mutation (SNP) | VAF 84/112 reads (75%) | SIFT tolerated (0.66); PolyPhen benign (0.006); catalogued as COSV59397577; called by muse, mutect2, varscan2
- CPLANE2 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65056959; called by muse, mutect2, varscan2
- CSMD3 | c.3056G>T p.G1019V (on ENST00000297405 / NM_001363185.1; = p.G915V on NM_052900.3) | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52202431; called by muse, mutect2
- CTNND2 | c.2401A>T p.K801* | Nonsense Mutation (SNP) | VAF 102/278 reads (37%) | catalogued as COSV58894543; called by muse, varscan2
- DCC | c.4020C>A p.H1340Q | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.773); catalogued as COSV71433343; called by muse, mutect2, varscan2
- DDIAS | c.716G>T p.W239L | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV61272367; called by muse, mutect2, varscan2
- DEDD2 | c.500G>A p.G167D | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.739); catalogued as COSV100260318; called by muse, mutect2, varscan2
- DEDD2 | c.499G>T p.G167C | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.894); catalogued as rs754504092, COSV100260320; called by muse, mutect2, varscan2
- DGLUCY | c.1141A>G p.N381D | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV56367002; called by muse, mutect2
- DMD | c.731G>A p.S244N | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as rs751368412, COSV55877040; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DMP1 | c.1504G>A p.G502R | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99218851; called by muse, mutect2, varscan2
- DMP1 | c.1505G>T p.G502V | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV99218853; called by muse, mutect2, varscan2
- DMXL1 | c.3653C>T p.S1218F | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV60707645, COSV60713018; called by muse, mutect2, varscan2
- DMXL1 | c.4480C>T p.L1494F | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV60713430; called by muse, mutect2, varscan2
- DPT | c.479T>C p.I160T | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs1412522184, COSV100892154, COSV63190138; called by muse, mutect2
- DSTYK | c.1818+1G>T p.X606_splice | Splice Site (SNP) | VAF 3/29 reads (10%) | catalogued as COSV100904636; called by muse, mutect2, varscan2
- EDIL3 | c.157G>T p.G53C | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56901629; called by muse, mutect2, varscan2
- EMB | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57482603; called by muse, mutect2, varscan2
- ENTHD1 | c.1102T>C p.S368P | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV57321110; called by muse, mutect2, varscan2
- EOMES | c.1634T>G p.L545W | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55412764; called by muse, mutect2, varscan2
- EPHA7 | c.1877A>T p.K626M | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65184279; called by muse, mutect2, varscan2
- EPS8L2 | c.863A>G p.K288R | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.044); catalogued as rs1219674573, COSV59348201; called by muse, mutect2
- ERAP2 | c.850-2A>T p.X284_splice | Splice Site (SNP) | VAF 14/45 reads (31%) | catalogued as rs375864675; called by muse, mutect2, varscan2
- ERBB3 | c.3902A>T p.Q1301L | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV57255494; called by muse, mutect2, varscan2
- ERBB4 | c.632C>T p.T211M | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.935); catalogued as rs771486473, COSV53540149; called by muse, mutect2, varscan2
- ESCO1 | c.1646-1G>A p.X549_splice | Splice Site (SNP) | VAF 66/193 reads (34%) | catalogued as COSV52520196; called by muse, mutect2, varscan2
- ETFBKMT | c.386C>T p.T129I | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99861613; called by muse, mutect2, varscan2
- EVC2 | c.3709G>C p.G1237R | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV60395212; called by muse, mutect2, varscan2
- EVI5 | c.2323G>A p.G775S | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.001); catalogued as COSV64827626; called by muse, mutect2, varscan2
- EWSR1 | c.1705G>T p.G569C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV58424361; called by muse, mutect2, varscan2
- FAM153B | c.838G>T p.V280L (on ENST00000253490; = p.V203L on NM_001265615.1) | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.198); catalogued as rs754415765, COSV53686824; called by muse, mutect2, varscan2
- FAM227B | c.79G>T p.E27* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100175340; called by muse, mutect2, varscan2
- FAM47C | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100792944, COSV63727203; called by muse, mutect2, varscan2
- FAM47C | c.1784C>T p.P595L | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.034); catalogued as rs782093572, COSV63727205; called by muse, varscan2
- FAT4 | c.5083A>C p.I1695L | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.046); catalogued as COSV67888938; called by muse, mutect2
- FBN2 | c.1149G>A p.M383I | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV52518887; called by muse, mutect2, varscan2
- FBXO24 | c.362G>A p.R121H (on ENST00000241071 / NM_033506.3; = p.R159H on NM_012172.5) | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.925); catalogued as rs770422214, COSV53826641; called by muse, mutect2, varscan2
- FCRL2 | c.1443G>C p.Q481H | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.969); catalogued as COSV63833350, COSV63833833; called by muse, mutect2, varscan2
- FFAR1 | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.351); catalogued as rs923079982, COSV50054716; called by muse, mutect2, varscan2
- FIG4 | c.206G>T p.R69L | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.044); catalogued as COSV57788242; called by muse, mutect2, varscan2
- FLG | c.11259G>T p.E3753D | Missense Mutation (SNP) | VAF 103/484 reads (21%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.968); catalogued as rs563905924, COSV64242850; called by muse, mutect2, varscan2
- FLG2 | c.3512C>A p.S1171Y | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.84); catalogued as COSV66169317; called by muse, mutect2, varscan2
- FOXN4 | c.785C>A p.S262Y | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV100142215, COSV100142226; called by muse, mutect2, varscan2
- FREM1 | c.877C>T p.Q293* | Nonsense Mutation (SNP) | VAF 36/121 reads (30%) | catalogued as COSV63087361; called by muse, mutect2, varscan2
- FRYL | c.120G>T p.L40F | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.945); catalogued as COSV51949642; called by muse, mutect2, varscan2
- FSTL4 | c.1126A>G p.K376E | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54773392; called by muse, mutect2, varscan2
- GABBR1 | c.2879A>G p.Y960C | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV63542902; called by muse, mutect2
- GABRA3 | c.826G>A p.G276S | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64799955; called by muse, mutect2, varscan2
- GCC2 | c.2287C>G p.L763V | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as COSV59177009; called by muse, mutect2, varscan2
- GMEB1 | c.127G>T p.G43C | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53794748; called by muse, mutect2, varscan2
- GNL1 | c.1297C>G p.P433A | Missense Mutation (SNP) | VAF 12/191 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV64921088; called by muse, mutect2
- GOLGA4 | c.3403C>T p.H1135Y | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV62711231; called by muse, mutect2, varscan2
- GRID2 | c.1254C>A p.C418* | Nonsense Mutation (SNP) | VAF 27/56 reads (48%) | catalogued as COSV56215669; called by muse, mutect2, varscan2
- GRIK4 | c.1252C>G p.L418V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as rs778132486, COSV70802975; called by muse, mutect2, varscan2
- GRM1 | c.2881G>T p.E961* | Nonsense Mutation (SNP) | VAF 29/140 reads (21%) | catalogued as COSV51164397; called by muse, mutect2, varscan2
- GTDC1 | c.71A>T p.E24V | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.455); catalogued as rs114787738, COSV99601163; called by muse, mutect2
- H2AC8 | c.221A>T p.N74I | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); catalogued as COSV55127051; called by muse, mutect2
- H2BC1 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.998); catalogued as COSV51237495; called by muse, mutect2, varscan2
- HAVCR1 | c.923T>G p.L308R | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100208446; called by muse, mutect2, varscan2
- HCN3 | c.1093A>G p.K365E | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as rs767979521, COSV64234319; called by muse, mutect2, varscan2
- HDAC9 | c.114C>A p.D38E | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.306); catalogued as COSV67774999; called by muse, mutect2
- HK1 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 75/188 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.042); catalogued as rs772637781, COSV100067252; called by muse, mutect2
- HK1 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as rs747711080, COSV53859600; called by muse, mutect2, varscan2
- HK2 | c.2051C>T p.A684V | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV51876057; called by muse, mutect2
- HNRNPCL1 | c.781G>T p.D261Y | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58612130; called by muse, mutect2, varscan2
- HSPG2 | c.10073A>T p.E3358V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.403); catalogued as COSV65933315; called by muse, mutect2, varscan2
- HTR1A | c.643T>C p.Y215H | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60501223; called by muse, mutect2, varscan2
- IDO1 | c.815G>T p.C272F | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53714450; called by muse, mutect2, varscan2
- IFT122 | c.1087T>C p.Y363H (on ENST00000348417 / NM_052989.3; = p.Y304H on NM_018262.4) | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56200993, COSV56203981; called by muse, mutect2, varscan2
- IGHMBP2 | c.1774G>T p.A592S | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.45); catalogued as COSV54823019; called by muse, mutect2, varscan2
- IKZF1 | c.1501del p.D501Tfs*9 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | catalogued as COSV100497902; called by mutect2, pindel
- IL12RB2 | c.1747C>A p.H583N | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as COSV52023899; called by muse, mutect2, varscan2
- IL1RAPL2 | c.609A>C p.E203D | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV61148447; called by muse, mutect2
- INHBC | c.337C>A p.R113S | Missense Mutation (SNP) | VAF 74/270 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.112); catalogued as COSV59005361; called by muse, varscan2
- IPMK | c.928G>T p.V310L | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.067); catalogued as COSV64243884; called by muse, mutect2, varscan2
- IQCH | c.2708C>G p.T903S | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60053955; called by muse, mutect2
- IRX5 | c.1171C>G p.P391A | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1319416971, COSV58058747, COSV58059047; called by muse, mutect2
- ISM1 | c.1199C>G p.A400G | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52605394, COSV52608443; called by muse, mutect2
- ITGAX | c.308C>A p.S103Y | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as COSV51642908; called by muse, mutect2, varscan2
- JAKMIP1 | c.1321T>G p.F441V | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as COSV51521915, COSV51533435, COSV51544425; called by muse, mutect2
- JAKMIP2 | c.115C>T p.Q39* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV54606388; called by muse, mutect2, varscan2
- JUN | c.256G>T p.G86W | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64664574; called by muse, mutect2, varscan2
- KAT6A | c.3291G>T p.Q1097H | Missense Mutation (SNP) | VAF 44/75 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV55906972; called by muse, mutect2, varscan2
- KCNA5 | c.911T>A p.M304K | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV52906545; called by muse, varscan2
- KCNA5 | c.934G>A p.V312M | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs1167570936, COSV52906552; called by muse, varscan2
- KCNA5 | c.1485C>G p.I495M | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.896); catalogued as COSV52906566, COSV52907574; called by muse, varscan2
- KCNJ12 | c.1061C>A p.T354K | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140886918, COSV59167868; called by muse, mutect2, varscan2
- KCTD8 | c.1054T>C p.C352R | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.135); catalogued as COSV63590192; called by muse, mutect2, varscan2
- KEAP1 | c.1709-1G>T p.X570_splice | Splice Site (SNP) | VAF 27/46 reads (59%) | catalogued as COSV99408032; called by muse, mutect2, varscan2
- KEL | c.891G>T p.K297N | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.42); catalogued as COSV62335599; called by muse, mutect2, varscan2
- KIF15 | c.2588T>C p.L863P | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58161465; called by muse, mutect2, varscan2
- KIF21A | c.2968G>T p.E990* (on ENST00000361418 / NM_001378440.1; = p.E977* on NM_017641.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 52/173 reads (30%) | catalogued as COSV62772551; called by muse, mutect2, varscan2
- KIF2B | c.941G>T p.G314V | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV52131431; called by muse, mutect2, varscan2
- KIRREL2 | c.2041C>A p.P681T | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.073); catalogued as COSV52876074; called by muse, mutect2, varscan2
- KLF4 | c.1204G>T p.G402C | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV65929038; called by muse, mutect2, varscan2
- KLHL1 | c.245C>G p.P82R | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.131); catalogued as rs776644824, COSV64773990, COSV64774969; called by muse, mutect2, varscan2
- KLHL2 | c.58G>T p.D20Y | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.187); catalogued as COSV56978115; called by muse, mutect2, varscan2
- KRT13 | c.451G>T p.D151Y | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1458787161, COSV55841063, COSV99877429; called by muse, mutect2, varscan2
- KRT34 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs200888573, COSV101222663, COSV67449953; called by muse, mutect2, varscan2
- KRT38 | c.211C>A p.P71T | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.034); catalogued as COSV55846243, COSV55846280; called by muse, mutect2, varscan2
- KRT4 | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV53407849; called by muse, mutect2
- KRTAP13-4 | c.147G>T p.R49S | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV61878890, COSV61879413; called by muse, mutect2, varscan2
- KRTAP5-10 | c.352G>T p.G118W | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.147); catalogued as COSV64794931; called by muse, mutect2
- LAMB1 | c.2513G>T p.G838V | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55965887; called by muse, mutect2, varscan2
- LAMB4 | c.328+1G>T p.X110_splice | Splice Site (SNP) | VAF 13/82 reads (16%) | catalogued as COSV52721141, COSV52730957; called by muse, mutect2, varscan2
- LANCL2 | c.466G>T p.A156S | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); catalogued as COSV54649841; called by muse, mutect2, varscan2
- LIFR | c.2654A>T p.Q885L | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.617); catalogued as COSV54691678; called by muse, mutect2, varscan2
- LIM2 | c.297C>A p.F99L (on ENST00000596399 / NM_001161748.2; = p.F141L on NM_030657.4) | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.438); catalogued as COSV55741410; called by muse, mutect2, varscan2
- LIN54 | c.2128A>C p.K710Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.031); catalogued as COSV61201588; called by muse, mutect2, varscan2
- LIPC | c.508G>T p.G170C | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774356974, COSV54423356, COSV54426567; called by muse, mutect2, varscan2
- LRRC45 | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as rs778842295, COSV60711723; called by muse, mutect2, varscan2
- LRRC4C | c.1019A>G p.Y340C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.64); catalogued as COSV53427748; called by muse, mutect2, varscan2
- LRRCC1 | c.935C>G p.S312C | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV100835489, COSV64483723; called by mutect2, varscan2
- MAB21L2 | c.979T>A p.F327I | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV58261992; called by muse, mutect2, varscan2
- MANSC1 | c.1154T>C p.L385P | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV67111127; called by muse, mutect2, varscan2
- MAP2 | c.3161G>T p.G1054V | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.02); catalogued as COSV52293914; called by muse, mutect2, varscan2
- MAP2K7 | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV67608503; called by muse, mutect2, varscan2
- MARCHF4 | c.1037C>A p.S346Y | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.547); catalogued as COSV99814614; called by muse, mutect2, varscan2
- MARK2 | c.337G>T p.V113F | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59284210; called by muse, mutect2
- MATN2 | c.1287C>A p.H429Q | Missense Mutation (SNP) | VAF 85/99 reads (86%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV54712655; called by muse, mutect2, varscan2
- MCHR1 | c.571A>G p.M191V | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.111); catalogued as COSV50761400; called by muse, mutect2, varscan2
- MDGA1 | c.2568C>A p.N856K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as COSV51796836; called by muse, varscan2
- MEGF8 | c.7175A>T p.Q2392L (on ENST00000251268 / NM_001271938.2; = p.Q2325L on NM_001410.3) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.025); catalogued as COSV52088223; called by muse, mutect2
- METTL18 | c.605G>C p.G202A | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53679562; called by muse, mutect2, varscan2
- MGAT3 | c.284G>T p.R95L | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV57866001; called by muse, mutect2, varscan2
- MMP1 | c.287A>T p.D96V | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59510633; called by muse, mutect2, varscan2
- MMP19 | c.1292C>A p.A431D | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59451679; called by muse, mutect2, varscan2
- MMP3 | c.1165G>T p.D389Y | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100242909, COSV55406993; called by muse, mutect2, varscan2
- MORC1 | c.497T>C p.M166T | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51721587; called by muse, mutect2, varscan2
- MOXD1 | c.1370G>T p.G457V | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100381723, COSV60945180; called by muse, mutect2, varscan2
- MTMR12 | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.133); catalogued as COSV53784950; called by muse, mutect2, varscan2
- MUC5B | c.208C>A p.P70T | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.454); catalogued as COSV71592664; called by muse, mutect2, varscan2
- MUC5B | c.2869C>A p.L957I | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.81); PolyPhen benign (0.017); catalogued as rs1363847910, COSV71592669; called by muse, mutect2, varscan2
- MYH11 | c.4051C>A p.Q1351K | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.731); catalogued as COSV55555894; called by muse, mutect2, varscan2
- MYH6 | c.3681G>T p.K1227N | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100676800; called by muse, varscan2
- MYLK4 | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 101/274 reads (37%) | catalogued as COSV51142905; called by muse, mutect2, varscan2
- MYO16 | c.2716C>T p.H906Y | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51787235; called by muse, mutect2
- NAV3 | c.2429A>G p.D810G | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as COSV57078532; called by muse, mutect2, varscan2
- NCKAP1L | c.3022del p.L1008Sfs*26 | Frame Shift Del (DEL) | VAF 17/68 reads (25%) | catalogued as COSV53203353; called by mutect2, pindel, varscan2
- NEK6 | c.714C>A p.Y238* | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as COSV100206515, COSV57218214; called by mutect2, varscan2
- NF1 | c.1481T>A p.L494* | Nonsense Mutation (SNP) | VAF 22/59 reads (37%) | catalogued as CM143322, COSV62206271; called by muse, mutect2, varscan2
- NF1 | c.5784del p.E1929Sfs*13 (on ENST00000358273 / NM_001042492.3; = p.E1908Sfs*13 on NM_000267.3) | Frame Shift Del (DEL) | VAF 17/75 reads (23%) | catalogued as COSV62201439; called by mutect2, pindel*, varscan2
- NLRP4 | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.078); catalogued as rs1164933028, COSV56715413; called by muse, mutect2, varscan2
- NOD2 | c.124G>A p.V42I | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.389); catalogued as COSV56051662; called by muse, mutect2, varscan2
- NOL4 | c.188A>T p.Q63L | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV52349582; called by muse, mutect2, varscan2
- NR2E1 | c.699G>T p.W233C | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as COSV64562086; called by muse, mutect2, varscan2
- NRIP1 | c.744A>T p.E248D | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.84); catalogued as COSV59657857; called by muse, mutect2, varscan2
- NT5C1A | c.342C>A p.Y114* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as rs140346943, COSV99348568; called by muse, mutect2
- NTAQ1 | c.304T>G p.L102V | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54874842; called by muse, mutect2
- NTM | c.415G>C p.V139L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV66181961, COSV66185563; called by muse, mutect2, varscan2
- NUP214 | c.5077A>C p.T1693P | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV63910225; called by muse, mutect2, varscan2
- OLFM1 | c.659C>G p.A220G (on ENST00000371793 / NM_001282611.2; = p.A202G on NM_014279.5) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.76); catalogued as COSV52962491, COSV52963844; called by mutect2, varscan2
- OLIG3 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62988682; called by muse, mutect2, varscan2
- OOSP2 | c.244-1G>T p.X82_splice | Splice Site (SNP) | VAF 30/57 reads (53%) | catalogued as COSV53929090; called by muse, mutect2, varscan2
- OR10A3 | c.554T>C p.L185P | Missense Mutation (SNP) | VAF 44/76 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62459601; called by muse, mutect2, varscan2
- OR10AG1 | c.56T>G p.F19C | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56631876; called by muse, mutect2
- OR10P1 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as rs191970757, COSV59007529; called by muse, mutect2, varscan2
- OR14A16 | c.373T>A p.C125S | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as COSV62926771; called by muse, mutect2, varscan2
- OR14A16 | c.106G>T p.A36S | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.486); catalogued as COSV62926498; called by muse, mutect2, varscan2
- OR2A5 | c.628C>A p.P210T | Missense Mutation (SNP) | VAF 79/167 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs376179956; called by muse, mutect2, varscan2
- OR2L8 | c.724A>T p.T242S | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV61727033; called by muse, mutect2, varscan2
- OR2V2 | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV60315714; called by muse, mutect2, varscan2
- OR4A16 | c.409C>A p.L137M | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV59041865, COSV59043466; called by muse, mutect2, varscan2
- OR4C16 | c.305C>G p.S102C | Missense Mutation (SNP) | VAF 100/227 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV58942354, COSV58942885; called by muse, mutect2, varscan2
- OR4D11 | c.221C>A p.S74Y | Missense Mutation (SNP) | VAF 98/212 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as COSV57585596; called by muse, mutect2, varscan2
- OR4D5 | c.562G>T p.A188S | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.817); catalogued as COSV58307454, COSV58309643; called by muse, mutect2
- OR51F1 | c.506T>G p.L169R | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.35); PolyPhen probably damaging (1); catalogued as COSV100598875, COSV58578784; called by muse, mutect2, varscan2
- OR52N4 | c.34G>T p.A12S | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57891375; called by muse, mutect2, varscan2
- OR56A3 | c.730A>T p.T244S | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61569272; called by muse, mutect2, varscan2
- OR5K3 | c.445T>C p.Y149H | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV67350181; called by muse, mutect2, varscan2
- OR6B1 | c.550G>T p.V184L | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV68770240; called by muse, mutect2, varscan2
- OR6C76 | c.324G>T p.E108D | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.213); catalogued as COSV60389238; called by muse, mutect2, varscan2
- OR8H2 | c.190del p.T65Lfs*19 | Frame Shift Del (DEL) | VAF 46/313 reads (15%) | catalogued as COSV57944806; called by mutect2, varscan2
- OR8K1 | c.636T>A p.N212K | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV54402856; called by muse, mutect2, varscan2
- PAM | c.1299G>C p.K433N | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV57214191; called by muse, mutect2, varscan2
- PASK | c.657G>T p.R219S | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV52154390; called by muse, mutect2
- PCBP1 | c.63C>G p.H21Q | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as COSV57850673; called by muse, mutect2, varscan2
- PCDH11X | c.645C>A p.Y215* | Nonsense Mutation (SNP) | VAF 32/107 reads (30%) | catalogued as COSV53472938, COSV53503148; called by muse, mutect2, varscan2
- PCDH15 | c.3335T>G p.L1112R | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV57325818; called by muse, mutect2, varscan2
- PCDHA2 | c.1624G>T p.V542L | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.019); catalogued as rs782611214, COSV65367093, COSV65367638; called by muse, mutect2, varscan2
- PCDHA9 | c.1783C>T p.R595C | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.969); catalogued as COSV65327445, COSV99061494; called by muse, mutect2, varscan2
- PCDHB12 | c.2027C>T p.A676V | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs1554287083, COSV53394426; called by muse, mutect2, varscan2
- PCDHB7 | c.103G>T p.V35L | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV50756095, COSV50775429; called by muse, mutect2, varscan2
- PCDHGA8 | c.623A>G p.H208R | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV53963698; called by muse, mutect2, varscan2
- PCLO | c.14972A>G p.Q4991R | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.439); catalogued as COSV61639934; called by muse, mutect2, varscan2
- PCM1 | c.2899C>A p.P967T | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as COSV61516923; called by muse, mutect2, varscan2
- PCOLCE2 | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs745693544, COSV55999593; called by muse, mutect2, varscan2
- PCSK5 | c.689C>G p.T230R | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV65090129; called by mutect2, varscan2
- PHF20L1 | c.2690A>T p.H897L | Missense Mutation (SNP) | VAF 114/159 reads (72%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV99621626; called by muse, mutect2, varscan2
- PHF20L1 | c.2691C>A p.H897Q | Missense Mutation (SNP) | VAF 115/161 reads (71%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99621631; called by muse, mutect2, varscan2
- PHLDB2 | c.2977G>T p.D993Y (on ENST00000393925 / NM_001134439.2; = p.D950Y on NM_145753.2) | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV67312187; called by muse, mutect2, varscan2
- PHLPP1 | c.3059C>G p.T1020R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53030462; called by muse, mutect2, varscan2
- PIK3R4 | c.1410A>T p.L470F | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV63241249; called by muse, mutect2, varscan2
- PKD1L1 | c.1842C>G p.I614M | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs769267602, COSV56967384; called by muse, mutect2, varscan2
- PLCB1 | c.3568C>A p.P1190T | Missense Mutation (SNP) | VAF 39/195 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs779246597, COSV100571672; called by muse, mutect2, varscan2
- PLCB1 | c.3569C>A p.P1190H | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV100571673; called by muse, mutect2, varscan2
- PLCB4 | c.78C>G p.Y26* | Nonsense Mutation (SNP) | VAF 16/29 reads (55%) | catalogued as COSV53804455; called by muse, mutect2, varscan2
- PLXNA4 | c.4417C>A p.P1473T | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58132170; called by muse, mutect2, varscan2
- PNLIP | c.790G>T p.D264Y | Missense Mutation (SNP) | VAF 47/186 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs755039876, COSV100981885; called by muse, mutect2, varscan2
- PNPLA5 | c.977C>A p.P326H | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV53374548; called by muse, mutect2, varscan2
- POMZP3 | c.317T>A p.F106Y | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99300616; called by muse, mutect2, varscan2
- POU1F1 | c.151C>A p.L51I | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.952); catalogued as COSV60156147; called by muse, mutect2
- PPFIBP1 | c.2287G>T p.V763F (on ENST00000318304 / NM_177444.3; = p.V757F on NM_003622.4) | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1363429727, COSV57292903; called by muse, mutect2, varscan2
- PPP1CB | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); catalogued as COSV56090784; called by muse, mutect2, varscan2
- PRKRIP1 | c.496G>T p.A166S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as COSV61350096; called by muse, mutect2, varscan2
- PRR16 | c.436C>G p.P146A (on ENST00000407149 / NM_001300783.2; = p.P123A on NM_016644.2) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as COSV65400607, COSV65401094; called by muse, mutect2, varscan2
- PRRC2B | c.5380G>A p.D1794N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754915526, COSV100261077, COSV57646725; called by mutect2, varscan2
- PRRC2C | c.164G>A p.R55H (on ENST00000367742; = p.R53H on NM_015172.4) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58905951; called by muse, varscan2
- PRRC2C | c.3064G>T p.V1022L (on ENST00000367742; = p.V1020L on NM_015172.4) | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV58906671; called by muse, mutect2
- PTCHD3 | c.1643G>C p.C548S | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.972); catalogued as COSV71256931; called by muse, mutect2, varscan2
- PTCHD4 | c.2317C>T p.L773F | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs1315066263, COSV59786569; called by muse, mutect2, varscan2
- PTPRJ | c.3793G>T p.V1265L | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV69252640; called by muse, mutect2, varscan2
- PTPRZ1 | c.6799G>C p.A2267P | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV66438204; called by muse, mutect2, varscan2
- PZP | c.867+1G>T p.X289_splice | Splice Site (SNP) | VAF 15/122 reads (12%) | catalogued as COSV54362497; called by muse, mutect2, varscan2
- PZP | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV54362514; called by muse, mutect2, varscan2
- RAB3IL1 | c.1066G>T p.A356S | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.095); catalogued as COSV57117769; called by muse, mutect2, varscan2
- RASGRF2 | c.3422A>G p.E1141G | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as rs1296046890, COSV54131371; called by muse, mutect2
- RASGRP3 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.694); catalogued as COSV67822505; called by muse, mutect2, varscan2
- RBP3 | c.1790C>A p.T597N | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.063); catalogued as rs781867669; called by muse, mutect2, varscan2
- RET | c.1481G>T p.R494M | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV60697389; called by muse, mutect2, varscan2
- RHPN2 | c.1902C>G p.I634M | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.352); catalogued as COSV54275439, COSV54280132; called by muse, mutect2, varscan2
- RIPOR3 | c.572G>A p.W191* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as COSV50391163; called by muse, mutect2, varscan2
- RMND1 | c.890A>G p.D297G | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV60550845; called by muse, mutect2, varscan2
- RSPO1 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.97); PolyPhen benign (0.006); catalogued as rs761409987, COSV62974352, COSV62974548; called by muse, mutect2, varscan2
- RUBCNL | c.742G>T p.D248Y | Missense Mutation (SNP) | VAF 65/175 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV59789405; called by muse, mutect2, varscan2
- RXFP3 | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.479); catalogued as rs773463511, COSV57506121; called by muse, mutect2, varscan2
- RYR1 | c.3763G>T p.E1255* | Nonsense Mutation (SNP) | VAF 26/63 reads (41%) | catalogued as COSV62099667, COSV62108758; called by muse, mutect2
- RYR1 | c.5389C>A p.R1797S | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT tolerated (0.72); PolyPhen benign (0.198); catalogued as COSV62099674, COSV62112620; called by muse, mutect2, varscan2
- RYR2 | c.3391G>T p.D1131Y | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV63659537, COSV63689837; called by muse, mutect2, varscan2
- RYR3 | c.4009G>T p.G1337* | Nonsense Mutation (SNP) | VAF 18/75 reads (24%) | catalogued as COSV66793515; called by muse, mutect2, varscan2
- SCAF11 | c.107G>T p.S36I | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV56977788; called by muse, mutect2, varscan2
- SDK2 | c.2596G>T p.E866* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as COSV66187672; called by muse, mutect2, varscan2
- SERPINA12 | c.1006G>T p.G336C | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV57944140; called by muse, mutect2, varscan2
- SHANK1 | c.6220C>A p.R2074S | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.398); catalogued as COSV53252620, COSV53263287; called by muse, mutect2, varscan2
- SIGLEC1 | c.3549C>A p.S1183R | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as COSV52465392; called by muse, mutect2, varscan2
- SLC22A25 | c.1518C>G p.I506M | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV60596525; called by muse, mutect2
- SLC7A13 | c.1340C>A p.A447D | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV52534946; called by muse, mutect2, varscan2
- SLFN5 | c.1322C>G p.A441G | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV55481562; called by muse, mutect2, varscan2
- SLITRK6 | c.1084C>A p.P362T | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs775661521, COSV68389372, COSV68389515; called by muse, mutect2, varscan2
- SLX4 | c.2207A>T p.Q736L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.376); catalogued as COSV99568302; called by muse, mutect2, varscan2
- SNX7 | c.1092A>C p.E364D | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.036); catalogued as COSV60269059; called by muse, mutect2, varscan2
- SNX9 | c.99+1G>T p.X33_splice | Splice Site (SNP) | VAF 16/52 reads (31%) | catalogued as COSV67584605; called by muse, mutect2, varscan2
- SOS1 | c.1604A>G p.N535S | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.052); catalogued as COSV67675664; called by muse, mutect2, varscan2
- SSTR1 | c.590G>T p.R197L | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV57455456, COSV57456425; called by muse, mutect2, varscan2
- SYNE2 | c.11040A>C p.L3680F | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV59953718; called by muse, mutect2, varscan2
- TAB2 | c.1940-1G>T p.X647_splice | Splice Site (SNP) | VAF 23/128 reads (18%) | catalogued as COSV53853028; called by mutect2, varscan2
- TAOK2 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); catalogued as COSV54236653; called by muse, mutect2, varscan2
- TBXT | c.894C>A p.N298K | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV51618491; called by muse, mutect2, varscan2
- TCERG1L | c.1271G>T p.C424F | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.045); catalogued as COSV64051074; called by muse, mutect2, varscan2
- TECTA | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV50700732; called by muse, mutect2, varscan2
- TEX2 | c.1337C>A p.P446Q | Missense Mutation (SNP) | VAF 67/176 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.192); catalogued as COSV51981972; called by muse, mutect2, varscan2
- TGS1 | c.2089G>A p.A697T | Missense Mutation (SNP) | VAF 101/121 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765338599, COSV52700585; called by muse, mutect2, varscan2
- THSD7B | c.1179A>C p.E393D | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV55695918; called by muse, mutect2, varscan2
- THSD7B | c.2190T>A p.C730* | Nonsense Mutation (SNP) | VAF 26/59 reads (44%) | catalogued as COSV55695936; called by muse, mutect2, varscan2
- TIAM1 | c.405C>A p.Y135* | Nonsense Mutation (SNP) | VAF 16/65 reads (25%) | catalogued as COSV54554850, COSV54558965; called by muse, mutect2, varscan2
- TMEM104 | c.121G>T p.G41W | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59109881, COSV59112324; called by muse, mutect2, varscan2
- TMX3 | c.446G>C p.R149T | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs1411205957, COSV55185794; called by muse, mutect2, varscan2
- TNIP2 | c.865C>G p.R289G | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.554); catalogued as COSV59569533; called by mutect2, varscan2
- TNR | c.1309C>A p.P437T | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54890024; called by muse, mutect2, varscan2
- TOR1AIP2 | c.1005G>T p.R335S | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as COSV62626260; called by muse, mutect2, varscan2
- TPO | c.1403G>A p.G468D | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61103349; called by muse, mutect2, varscan2
- TRIM14 | c.89G>T p.R30L | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58354434; called by muse, mutect2, varscan2
- TROAP | c.160C>G p.P54A | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV57744656; called by muse, mutect2
- TTN | c.9587A>G p.Y3196C (on ENST00000591111; = p.Y3150C on NM_003319.4) | Missense Mutation (SNP) | VAF 8/102 reads (8%) | PolyPhen probably damaging (0.999); catalogued as rs1238502159, COSV60113732; called by muse, mutect2
- TTN | c.1801-1G>T p.X601_splice (on ENST00000591111; = p.X555_splice on NM_003319.4) | Splice Site (SNP) | VAF 18/46 reads (39%) | catalogued as COSV60113793, COSV60253169; called by muse, varscan2
- TUBA3D | c.272A>G p.Q91R | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.621); catalogued as COSV58312045; called by muse, mutect2, varscan2
- TULP4 | c.3493C>T p.R1165* | Nonsense Mutation (SNP) | VAF 27/122 reads (22%) | catalogued as COSV65581925; called by muse, mutect2, varscan2
- TULP4 | c.3494G>C p.R1165P | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100893662; called by muse, mutect2, varscan2
- TXLNB | c.787C>A p.Q263K | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV100625212, COSV62727377; called by muse, mutect2, varscan2
- UBE3B | c.3034G>C p.G1012R | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100688971, COSV61075120; called by muse, mutect2, varscan2
- USH1C | c.1204C>A p.P402T | Missense Mutation (SNP) | VAF 136/225 reads (60%) | SIFT tolerated (0.4); PolyPhen benign (0.024); catalogued as COSV50020065; called by muse, mutect2, varscan2
- USH2A | c.13495C>A p.L4499I | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56381227; called by muse, mutect2, varscan2
- USH2A | c.3675C>A p.S1225R | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV100232837, COSV56381241; called by muse, mutect2
- VAMP3 | c.154G>T p.A52S | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.627); catalogued as COSV50012597, COSV50012626; called by muse, mutect2, varscan2
- VN1R2 | c.411G>C p.L137F | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV59038603; called by muse, mutect2, varscan2
- VWC2L | c.569T>G p.V190G | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56971526; called by muse, mutect2, varscan2
- XIRP2 | c.6958G>T p.D2320Y (on ENST00000628543; = p.D2495Y on NM_152381.6) | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV54706362; called by muse, mutect2, varscan2
- XKR7 | c.1199G>T p.G400V | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.388); catalogued as COSV73813215, COSV73813372; called by muse, mutect2
- YIF1B | c.680G>T p.G227V (on ENST00000339413 / NM_001039673.3; = p.G212V on NM_001039671.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56650947, COSV56651721; called by muse, mutect2
- ZBTB22 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV56470116; called by muse, mutect2, varscan2
- ZC3H18 | c.600A>G p.I200M | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.541); catalogued as rs763678102, COSV56325331; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1004A>G p.D335G | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60157287; called by muse, mutect2, varscan2
- ZNF114 | c.541G>T p.G181W | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV59944488; called by muse, mutect2, varscan2
- ZNF221 | c.1787A>C p.E596A | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV52109867; called by muse, mutect2
- ZNF496 | c.434G>T p.S145I | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.086); catalogued as COSV54178098; called by muse, mutect2, varscan2
- ZNF500 | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 4/9 reads (44%) | catalogued as COSV54788505; called by muse, mutect2, varscan2
- ZNF512B | c.1388G>T p.G463V | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.376); catalogued as COSV53871967; called by muse, mutect2, varscan2
- ZNF549 | c.63A>T p.K21N | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV53725810; called by muse, mutect2, varscan2
- ZNF585A | c.1379A>G p.H460R (on ENST00000292841 / NM_001288800.2; = p.H405R on NM_152655.3) | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53064479; called by muse, mutect2
- ZNF608 | c.3726G>A p.W1242* | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | catalogued as COSV60438465; called by muse, mutect2
- ZNF700 | c.1309G>A p.G437S | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.221); catalogued as rs765415938, COSV54311348, COSV54311818; called by muse, mutect2, varscan2
- ZNF792 | c.369G>T p.E123D | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV68693523; called by muse, mutect2, varscan2
- ZSCAN4 | c.958G>A p.V320I | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV56593353; called by muse, mutect2, varscan2
- ZSWIM2 | c.569C>A p.S190Y | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs750005195, COSV54576156; called by muse, mutect2, varscan2
- ZWILCH | c.311G>C p.G104A | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.089); catalogued as COSV57180739; called by muse, mutect2, varscan2
- ZZEF1 | c.4245C>G p.S1415R | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.068); catalogued as COSV67558013; called by muse, mutect2, varscan2
- ANK3 | c.5539_5550del p.K1847_A1850del | In Frame Del (DEL) | VAF 19/223 reads (9%) | called by mutect2, pindel
- APOBEC3H | c.433dup p.W145Lfs*17 | Frame Shift Ins (INS) | VAF 20/70 reads (29%) | called by mutect2, pindel, varscan2
- ATP9A | c.1555del p.R519Efs*8 | Frame Shift Del (DEL) | VAF 15/84 reads (18%) | called by mutect2, pindel, varscan2
- CALN1 | c.519dup p.E174Rfs*3 (on ENST00000329008 / NM_001017440.3; = p.E216Rfs*3 on NM_031468.4) | Frame Shift Ins (INS) | VAF 13/108 reads (12%) | called by mutect2, varscan2
- CAND1 | c.2852_2854del p.V951del | In Frame Del (DEL) | VAF 14/60 reads (23%) | called by pindel, varscan2
- CERS6 | c.759dup p.A254Cfs*8 | Frame Shift Ins (INS) | VAF 24/64 reads (38%) | called by mutect2, pindel, varscan2
- DDB1 | c.1588_1589insT p.S530Mfs*8 | Frame Shift Ins (INS) | VAF 8/86 reads (9%) | called by muse*, mutect2
- IGHV3-13 | c.245T>A p.V82E | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- IGKV2-24 | c.31C>A p.L11I | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2
- LAMA1 | c.8283_8291del p.D2762_A2764del | In Frame Del (DEL) | VAF 6/37 reads (16%) | called by mutect2, pindel, varscan2
- MSMB | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NELL2 | c.1076_1077dup p.E360Mfs*8 | Frame Shift Ins (INS) | VAF 4/46 reads (9%) | called by mutect2, pindel
- OR1A2 | c.746del p.L249Yfs*14 | Frame Shift Del (DEL) | VAF 15/100 reads (15%) | called by mutect2, pindel, varscan2
- OR1N1 | c.376del p.H126Tfs*9 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | called by mutect2, pindel, varscan2
- PI4KB | c.1096del p.R366Efs*33 (on ENST00000368873 / NM_001369623.1; = p.R378Efs*33 on NM_002651.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | called by mutect2, varscan2
- PRAMEF20 | c.159G>T p.K53N | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- TRAV5 | c.45G>T p.Q15H | Missense Mutation (SNP) | VAF 59/342 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- ZNF26 | c.49A>T p.K17* | Nonsense Mutation (SNP) | VAF 21/176 reads (12%) | called by muse, mutect2, varscan2
- A1CF | c.1089C>A p.A363= | Silent (SNP) | VAF 38/123 reads (31%) | catalogued as COSV50972148, COSV50982796; called by muse, mutect2, varscan2
- ABHD2 | c.1089A>T p.R363= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV61774494; called by muse, mutect2, varscan2
- ALKBH3 | c.222A>G p.R74= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV57024620; called by muse, mutect2, varscan2
- AMER3 | c.528G>T p.S176= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as rs776935592, COSV58467357, COSV58469465; called by muse, mutect2, varscan2
- ANO1 | c.1254C>T p.L418= | Silent (SNP) | VAF 12/13 reads (92%) | catalogued as rs1379535562, COSV60285659; called by mutect2, varscan2
- ARHGEF10 | c.3108C>T p.Y1036= (on ENST00000398564; = p.Y1011= on NM_014629.4) | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as rs144293528; called by muse, mutect2
- ASTL | c.790C>A p.R264= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as rs760331210, COSV60904483; called by muse, mutect2, varscan2
- ATP2B2 | c.2131C>A p.R711= (on ENST00000352432; = p.R677= on NM_001683.5) | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100660198, COSV59509014; called by muse, mutect2, varscan2
- BOC | c.2481C>A p.A827= | Silent (SNP) | VAF 49/134 reads (37%) | catalogued as COSV56352349; called by muse, mutect2, varscan2
- CAMK2B | c.1557C>A p.P519= | Silent (SNP) | VAF 16/31 reads (52%) | called by muse, mutect2
- CBY2 | c.624C>A p.G208= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV60118577; called by muse, mutect2, varscan2
- CDH20 | c.138C>G p.L46= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV53011218; called by muse, mutect2, varscan2
- CDX2 | c.882C>A p.G294= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV66829587; called by muse, mutect2, varscan2
- CHL1 | c.1885C>A p.R629= (on ENST00000397491 / NM_001253387.1; = p.R645= on NM_006614.4) | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as COSV56591175, COSV56595437; called by muse, mutect2, varscan2
- COL13A1 | c.1998T>C p.H666= (on ENST00000398978 / NM_001130103.2; = p.H594= on NM_080798.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs757830252, COSV62570895; called by muse, mutect2, varscan2
- COL4A1 | c.3654G>A p.Q1218= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV65427018; called by muse, mutect2, varscan2
- COL9A1 | c.267G>A p.L89= | Silent (SNP) | VAF 5/97 reads (5%) | catalogued as rs1313732948, COSV61833528; called by muse, mutect2
- CTSV | c.978C>T p.A326= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as rs149018053; called by muse, mutect2, varscan2
- DCLK1 | c.975G>T p.P325= | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as rs151019237, COSV55190671, COSV99709400; called by muse, mutect2, varscan2
- DHX34 | c.2031G>T p.L677= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV60895782; called by muse, mutect2, varscan2
- DIRAS2 | c.93A>G p.T31= | Silent (SNP) | VAF 30/129 reads (23%) | catalogued as COSV65370437; called by muse, mutect2, varscan2
- DISP3 | c.1758C>A p.A586= | Silent (SNP) | VAF 47/121 reads (39%) | catalogued as COSV53829094; called by muse, mutect2, varscan2
- DST | c.19224T>A p.G6408= (on ENST00000361203 / NM_001374722.1; = p.G4105= on NM_015548.5) | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV55019283; called by muse, mutect2
- EGFLAM | c.618C>G p.L206= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as rs150656160, COSV100472284, COSV59305017; called by muse, mutect2, varscan2
- EIF4E1B | c.162C>A p.P54= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs1048302519, COSV53780608; called by muse, mutect2, varscan2
- FMR1 | c.213A>T p.A71= | Silent (SNP) | VAF 42/134 reads (31%) | catalogued as COSV54424675; called by muse, mutect2, varscan2
- FOXN4 | c.786C>G p.S262= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV100142224, COSV54494286; called by muse, mutect2, varscan2
- FREM2 | c.4806C>A p.I1602= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV54840491; called by muse, mutect2, varscan2
- FRMPD2 | c.1134G>A p.E378= | Silent (SNP) | VAF 17/108 reads (16%) | catalogued as COSV59718879; called by muse, mutect2, varscan2
- GIMAP1 | c.324G>A p.S108= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV56188450; called by muse, mutect2, varscan2
- GPR141 | c.675G>A p.L225= | Silent (SNP) | VAF 65/147 reads (44%) | catalogued as COSV57732585; called by muse, mutect2, varscan2
- GRK6 | c.1611G>T p.L537= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV100586962; called by muse, mutect2, varscan2
- GRM3 | c.570C>A p.T190= | Silent (SNP) | VAF 9/123 reads (7%) | catalogued as rs754123274, COSV64469532, COSV64473417; called by muse, mutect2
- HDAC9 | c.1209A>G p.E403= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV67775009; called by muse, mutect2
- HECTD3 | c.1230C>A p.L410= | Silent (SNP) | VAF 28/111 reads (25%) | catalogued as COSV55800680; called by muse, mutect2, varscan2
- HK1 | c.90G>T p.R30= | Silent (SNP) | VAF 74/186 reads (40%) | catalogued as COSV100067265, COSV53853143; called by muse, mutect2
- HVCN1 | c.153G>A p.E51= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV54372468, COSV99657573; called by muse, mutect2, varscan2
- IGLV2-11 | c.339A>T p.A113= | Silent (SNP) | VAF 32/136 reads (24%) | catalogued as rs763481939; called by muse, mutect2, varscan2
- IL12A | c.600G>T p.L200= | Silent (SNP) | VAF 34/206 reads (17%) | catalogued as COSV59759472; called by muse, mutect2, varscan2
- ITK | c.1749C>A p.A583= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV70062832; called by muse, mutect2, varscan2
- KCNA5 | c.1509C>A p.A503= | Silent (SNP) | VAF 43/100 reads (43%) | catalogued as COSV52906572, COSV52908509; called by muse, varscan2
- KCNA5 | c.1776C>T p.S592= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs768185530, COSV52906584; called by muse, mutect2, varscan2
- KCNJ6 | c.924A>G p.L308= | Silent (SNP) | VAF 30/104 reads (29%) | catalogued as rs563198413, COSV55715545; called by muse, mutect2, varscan2
- KIAA1217 | c.213G>T p.G71= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV64600630, COSV64607232; called by muse, mutect2, varscan2
- KIF4B | c.2871A>G p.Q957= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV70529866, COSV70531085; called by muse, mutect2, varscan2
- KIR2DL4 | c.891C>A p.P297= (on ENST00000396284; = p.P258= on NM_001080772.2) | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as rs1382473111; called by muse, mutect2, varscan2
- KIR3DL3 | c.642C>T p.D214= | Silent (SNP) | VAF 96/210 reads (46%) | called by muse, mutect2, varscan2
- KRT13 | c.450G>T p.R150= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as COSV99877432; called by muse, mutect2, varscan2
- KRT5 | c.1005G>T p.L335= | Silent (SNP) | VAF 28/135 reads (21%) | catalogued as COSV52861155; called by muse, mutect2, varscan2
- KRT75 | c.360C>A p.G120= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as COSV52873236; called by muse, mutect2, varscan2
- KRTAP23-1 | c.156C>A p.L52= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV61935685; called by muse, mutect2, varscan2
- LRFN5 | c.477A>G p.L159= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV53259948; called by muse, mutect2, varscan2
- LTBP2 | c.3408G>A p.V1136= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as rs768712611, COSV56209286; called by muse, mutect2, varscan2
- MED13L | c.4137G>C p.P1379= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV56121816, COSV56131669; called by muse, mutect2, varscan2
- MON1B | c.114G>T p.P38= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV50248030; called by muse, mutect2
- MUC3A | c.8949G>A p.Q2983= | Silent (SNP) | VAF 11/110 reads (10%) | catalogued as rs777762866, COSV60217203; called by muse, mutect2
- MYO1B | c.2247G>A p.Q749= | Silent (SNP) | VAF 19/132 reads (14%) | catalogued as COSV58432079; called by muse, mutect2, varscan2
- NFIC | c.231G>T p.L77= | Silent (SNP) | VAF 38/71 reads (54%) | catalogued as COSV59413197; called by muse, mutect2, varscan2
- NKAPL | c.243C>T p.Y81= | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as COSV59198153; called by muse, mutect2
- NOX4 | c.933C>A p.I311= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as COSV54455016; called by muse, mutect2, varscan2
- NPC1L1 | c.2478G>T p.G826= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as COSV56926040; called by muse, mutect2, varscan2
- OR10K2 | c.45C>T p.L15= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as rs373065917; called by muse, mutect2, varscan2
- OR1L8 | c.69G>A p.E23= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV59186609; called by muse, mutect2, varscan2
- OR2G3 | c.243C>T p.T81= | Silent (SNP) | VAF 34/404 reads (8%) | catalogued as COSV100180709, COSV60681528; called by muse, mutect2
- OR8H1 | c.636A>C p.T212= | Silent (SNP) | VAF 11/117 reads (9%) | catalogued as COSV57294395; called by muse, mutect2, varscan2
- PCDH12 | c.1350C>A p.I450= | Silent (SNP) | VAF 31/110 reads (28%) | catalogued as COSV51521883; called by muse, mutect2, varscan2
- PCDH15 | c.1758G>C p.A586= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV57325855; called by muse, mutect2, varscan2
- PCDHGA8 | c.2085G>T p.V695= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV53963708; called by muse, mutect2, varscan2
- PCSK1 | c.2085C>A p.I695= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV60735869; called by muse, mutect2, varscan2
- PHOX2A | c.372G>T p.A124= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV53356314; called by muse, mutect2, varscan2
- PIK3CG | c.174G>T p.L58= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV63249236, COSV63250013; called by muse, mutect2, varscan2
- PLAA | c.2112A>G p.T704= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs932417293, COSV68305054; called by muse, mutect2
- PNLIP | c.789G>C p.V263= | Silent (SNP) | VAF 45/184 reads (24%) | catalogued as COSV100981882; called by muse, mutect2, varscan2
- POTEE | c.2793C>A p.A931= | Silent (SNP) | VAF 41/333 reads (12%) | catalogued as COSV58233109; called by muse, mutect2, varscan2
- PTN | c.246C>A p.T82= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as COSV100780810, COSV61966170; called by muse, mutect2, varscan2
- RHO | c.984G>A p.L328= | Silent (SNP) | VAF 8/144 reads (6%) | catalogued as COSV56213728; called by muse, mutect2
- RNFT2 | c.621A>C p.S207= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV57486138; called by muse, mutect2, varscan2
- SEC14L1 | c.1710G>A p.S570= | Silent (SNP) | VAF 35/367 reads (10%) | catalogued as rs202169419, COSV66722565, COSV66725771; called by muse, mutect2
- SETD5 | c.3780C>T p.S1260= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as COSV100200466, COSV56711966; called by muse, mutect2, varscan2
- SFI1 | c.1492C>A p.R498= (on ENST00000400288 / NM_001007467.3; = p.R467= on NM_014775.4) | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV66289790, COSV66291159; called by muse, mutect2, varscan2
- SLC24A4 | c.1626C>T p.T542= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs1310788590, COSV54114286; called by muse, mutect2, varscan2
- SLC6A15 | c.2046G>T p.P682= | Silent (SNP) | VAF 74/162 reads (46%) | catalogued as rs564047485, COSV57020866, COSV57024726; called by muse, mutect2, varscan2
- SMCHD1 | c.4692C>T p.P1564= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs1268102041, COSV55259161; called by mutect2, varscan2
- SP4 | c.1923A>T p.P641= | Silent (SNP) | VAF 17/128 reads (13%) | catalogued as COSV56023228; called by muse, mutect2, varscan2
- SPPL2C | c.999C>T p.T333= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as rs754600209, COSV61292740; called by muse, mutect2, varscan2
- ST3GAL1 | c.975G>T p.T325= | Silent (SNP) | VAF 175/233 reads (75%) | catalogued as COSV60612761, COSV60613574; called by muse, mutect2, varscan2
- SULT4A1 | c.282G>A p.P94= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs200810567; called by mutect2, varscan2
- TAF7L | c.600T>C p.T200= | Silent (SNP) | VAF 37/66 reads (56%) | catalogued as COSV61257223; called by muse, mutect2, varscan2
- TAPBPL | c.321C>A p.A107= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as COSV56947182; called by muse, mutect2, varscan2
- TBC1D15 | c.1887G>T p.G629= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as rs1440948547, COSV59849834, COSV59850990; called by muse, mutect2, varscan2
- TBX3 | c.645C>T p.D215= | Silent (SNP) | VAF 9/142 reads (6%) | catalogued as COSV57472412; called by muse, mutect2
- TGM6 | c.1827C>A p.T609= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV52479226; called by muse, mutect2, varscan2
- TMTC1 | c.832C>A p.R278= (on ENST00000539277 / NM_001193451.2; = p.R170= on NM_175861.3) | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV55483804, COSV55486953; called by muse, mutect2, varscan2
- TNXB | c.3744G>T p.P1248= (on ENST00000647633; = p.P1001= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV64473963, COSV64480404; called by muse, mutect2, varscan2
- TRRAP | c.417A>G p.L139= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as rs1189139817, COSV62846167; called by muse, mutect2, varscan2
- TSPEAR | c.840G>A p.V280= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as rs782126412, COSV59965886; called by muse, mutect2, varscan2
- TTC37 | c.567A>T p.A189= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV62455162; called by muse, mutect2, varscan2
- ULBP2 | c.702C>T p.L234= | Silent (SNP) | VAF 9/101 reads (9%) | catalogued as COSV100951252; called by muse, mutect2
- ULK1 | c.1869C>T p.S623= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs1235454507, COSV58857343; called by muse, mutect2, varscan2
- WWC1 | c.1479G>T p.R493= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV54652147; called by muse, mutect2, varscan2
- XKR3 | c.753G>T p.V251= | Silent (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2, varscan2
- ZEB2 | c.2625G>T p.L875= | Silent (SNP) | VAF 49/126 reads (39%) | catalogued as COSV57958203; called by muse, mutect2, varscan2
- ZNF26 | c.48C>T p.F16= | Silent (SNP) | VAF 22/177 reads (12%) | called by muse, mutect2, varscan2
- ZNF407 | c.1086T>G p.V362= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV55256132; called by muse, mutect2, varscan2
- ZNF532 | c.1266G>T p.A422= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as COSV60173587; called by muse, mutect2, varscan2
- ZNF638 | c.1554G>C p.P518= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as COSV52488809; called by muse, mutect2, varscan2
- ZNF681 | c.96G>T p.V32= | Silent (SNP) | VAF 35/163 reads (21%) | catalogued as COSV68074450, COSV68075177; called by muse, mutect2, varscan2
- ZNF813 | c.1140G>A p.E380= | Silent (SNP) | VAF 64/134 reads (48%) | catalogued as COSV67176780; called by muse, mutect2, varscan2
- ZSWIM5 | c.3235C>A p.R1079= | Silent (SNP) | VAF 35/56 reads (63%) | catalogued as COSV55800687; called by muse, mutect2, varscan2
- BIRC8 | n.1668C>T | RNA (SNP) | VAF 17/93 reads (18%) | catalogued as COSV58843703; called by muse, mutect2, varscan2
- BIRC8 | n.1068G>T | RNA (SNP) | VAF 27/49 reads (55%) | catalogued as COSV101461368, COSV70347216; called by muse, mutect2, varscan2
- CDH18 | c.-2C>A | 5'UTR (SNP) | VAF 14/37 reads (38%) | catalogued as rs1188464332, COSV99936773; called by muse, mutect2, varscan2
- DCHS2 | n.196G>T | RNA (SNP) | VAF 7/17 reads (41%) | catalogued as COSV100252464; called by muse, mutect2, varscan2
- FAM153CP | chr5:178055934 G>A | 3'Flank (SNP) | VAF 13/60 reads (22%) | called by muse, mutect2, varscan2
- GAS8 | c.90+1486G>T | Intron (SNP) | VAF 7/29 reads (24%) | catalogued as rs1259858078, COSV99244078; called by muse, mutect2, varscan2
- GCK | c.46-4620C>A | Intron (SNP) | VAF 25/43 reads (58%) | catalogued as COSV100596437; called by muse, mutect2, varscan2
- HAVCR1 | c.-2T>A | 5'UTR (SNP) | VAF 4/23 reads (17%) | catalogued as COSV100208451; called by muse, mutect2
- IGF2 | c.326-509C>A | Intron (SNP) | VAF 6/10 reads (60%) | catalogued as COSV56099541; called by muse, mutect2
- KLK8 | c.71-50C>T | Intron (SNP) | VAF 18/67 reads (27%) | catalogued as COSV99144030; called by muse, mutect2, varscan2
- MIR134 | n.60A>T | RNA (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- PDE4B | c.281+74275G>T | Intron (SNP) | VAF 35/70 reads (50%) | catalogued as COSV100304275; called by muse, mutect2, varscan2
- RRM2 | n.559G>T | RNA (SNP) | VAF 37/83 reads (45%) | catalogued as rs376592690; called by muse, mutect2, varscan2
- TUBB7P | n.971G>T | RNA (SNP) | VAF 10/28 reads (36%) | called by mutect2, varscan2
- XIRP2 | c.*44G>T | 3'UTR (SNP) | VAF 9/62 reads (15%) | catalogued as COSV104401500, COSV99745256; called by muse, mutect2, varscan2
